Surgical pathology report (de-identified scan), TCGA case TCGA-62-A46S, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A46S-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, left, upper lobe: 22.0 x 15.0 x 7.0 cm

tumor: 8.0 x 7.0 x 4.0 cm

Diagnosis:

Adenocarcinoma, papillary

Infiltration of pleura visceralis

pT2, pN0 (0/37), pMx, G2

1CD-0-3

adenocarcinoma, papillary, nos 8260/3

Site: lung, upper lobe c34.1

W
9/24/12

Pathologist:

Site/AA Discrepancy		

W
8/21/12

Source: NCI Genomic Data Commons file 5953afe5-fab9-4b0c-8064-a226338a863b (TCGA-62-A46S.56821636-8883-494F-A808-61AD827CE524.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).